Somatic mutation profile of tumor specimen ALCH-B2P5-TTP1-A (aliquot ALCH-B2P5-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2P5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,948 days).
Specimen ALCH-B2P5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4637cf1-9e76-4233-802c-3b347ebeb3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2P5-NB1-A (Blood Derived Normal), aliquot ALCH-B2P5-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4c3172d-74ff-455a-acba-137e9f81bea5

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 4, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 9/170 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- SI | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs763490929; called by muse, mutect2
- ZSCAN16 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.469); catalogued as COSV61258521; called by muse, mutect2
- AGO4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- ATP10B | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BBS9 | c.1727A>T p.N576I (on ENST00000242067 / NM_001348036.1; = p.N536I on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- CYP2C8 | c.1106C>A p.A369E | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2
- EIF4A2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2
- KRT80 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- MSL2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- NSMF | c.988G>A p.E330K (on ENST00000371475 / NM_001130969.3; = p.E328K on NM_015537.4) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- RPS6KA6 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- SOX17 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.14); called by muse, mutect2
- OLFML1 | c.900C>T p.G300= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- THUMPD3 | c.675G>A p.L225= | Silent (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- DST | c.4296+4338G>C | Intron (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- FCGR2A | c.364+29C>T | Intron (SNP) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- PRKCG | c.-257G>A | 5'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, varscan2
- ZNF746 | c.520+968G>T | Intron (SNP) | VAF 9/242 reads (4%) | catalogued as COSV61406826; called by muse, mutect2
- ZNF746 | c.520+967G>T | Intron (SNP) | VAF 9/251 reads (4%) | called by muse, mutect2
